Surgical pathology report (de-identified scan), TCGA case TCGA-QK-AA3K, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Emory University - Winship Cancer Inst., specimen TCGA-QK-AA3K-01A (Primary Tumor).

[page 1 of 10]
ICD O-3
Carcinoma, squamous cell NOS
Site: Tongue NOS C02.9
807613
J. 1/17/14

Case Report

Case Report

Surgical Pathology Report Case:

Authorizing Provider:

Ordering Location:

Pathologist:

Signed Out:

Specimens: A) - Nasopharynx/Oropharynx

B) - Nasopharynx/Oropharynx

C) - Nasopharynx/Oropharynx

D) - Nasopharynx/Oropharynx

E) - Soft Tissue, Other, Level 1a neck contents

F) - Soft Tissue, Other, Right level 2b

G) - Soft Tissue, Other, Right facial node

H) - Soft Tissue, Other, Right composite

I) - Soft Tissue, Other, Right neck level 3,4,5

J) - Soft Tissue, Other, Left level 1

K) - Soft Tissue, Other, Left facial node

L) - Oral Mucosa/Gingiva, Posterior oral mucosa

Gross description

Specimen - A

The specimen is received fresh. Both the original label and the label indicate the patient's name is [REDACTED] and both labels have the same hospital number.

[page 2 of 10]
SPECIMEN TYPE AND LOCATION INDICATED ON THE CONTAINER LABEL: Buccal Margin

The specimen consists of a portion of mucosal tissue measuring 3.2 x 0.8 x 0.4 cm. The specimen is entirely submitted for frozen section diagnosis and the residual tissue from the cryoblock is submitted as indicated in cassette summary.

Cassette summary:
FSA1: Buccal margin

Specimen - B

The specimen is received fresh. Both the original label and the label indicate the patient's name is [REDACTED] and both labels have the same hospital number.

SPECIMEN TYPE AND LOCATION INDICATED ON THE CONTAINER LABEL: Lingual Margin #1

The specimen consists of a portion of mucosal tissue measuring 2.0 x 1.8 x 0.2 cm. The specimen is entirely submitted for frozen section diagnosis and the residual tissue from the cryoblock is submitted as indicated in cassette summary.

Cassette summary:
FSB1: Lingual margin #1

Specimen - C

The specimen is received fresh. Both the original label and the label indicate the patient's name is [REDACTED] and both labels have the same hospital number.

SPECIMEN TYPE AND LOCATION INDICATED ON THE CONTAINER LABEL: Lingual Margin #2

The specimen consists of a portion of mucosal tissue measuring 2.4 x 0.6 x 0.3 cm. The specimen is entirely submitted for frozen section diagnosis and the residual tissue from the cryoblock is submitted as indicated in cassette summary.

Cassette summary:
FSC1: Lingual margin #2

Specimen - D

The specimen is received fresh. Both the original label and the label indicate the patient's name is [REDACTED] and both labels have the same hospital number.

[page 3 of 10]
SPECIMEN TYPE AND LOCATION INDICATED ON THE CONTAINER LABEL: Deep tissue margin

The specimen consists of a portion of mucosal tissue measuring 1.1 x 1.0 x 0.3 cm. The specimen is entirely submitted for frozen section diagnosis and the residual tissue from the cryoblock is submitted as indicated in cassette summary.

Cassette summary:

FSD1: Deep tissue margin

Specimen - E

The specimen is received fresh. Both the original label and the label indicate the patient's name is [REDACTED] and both labels have the same hospital number.

SPECIMEN TYPE AND LOCATION INDICATED ON THE CONTAINER LABEL: Level 1A neck contents

The specimen consists of a portion of unoriented white fibrofatty tissue measuring 3.0 x 1.6 x 0.4 cm. Potential lymph nodes are submitted as indicated in cassette summary.

Cassette summary:

E1: One possible lymph node bisected

Specimen - F

The specimen is received fresh. Both the original label and the label indicate the patient's name is [REDACTED] and both labels have the same hospital number.

SPECIMEN TYPE AND LOCATION INDICATED ON THE CONTAINER LABEL: Right level 2B

The specimen consists of a portion of unoriented white fibrofatty tissue measuring 4.0 x 3.0 x 1.6 cm that weighs 7.4 g. There is an attached white lymph node that measures 1.6 x 1.4 x 1.4. The specimen is serially sectioned. Representative sections are submitted as indicated in cassette summary.

Cassette summary:

F1: Attached lymph node section

F2: Representative sections of salivary gland

Specimen - G

The specimen is received fresh. Both the original label and the label indicate the

[page 4 of 10]
patient's name is [REDACTED] and both labels have the same hospital number.

SPECIMEN TYPE AND LOCATION INDICATED ON THE CONTAINER LABEL: Right facial node

The specimen consists of a portion of unoriented white fibrofatty tissue measuring 2.6 x 1.0 x 0.8 cm. Representative sections are submitted as indicated in cassette summary.

Cassette summary:

G1: One lymph node bisected

H. Specimen - H

The specimen is received fresh. Both the original label and the [REDACTED] label indicate the patient's name is [REDACTED] and both labels have the same hospital number.

SPECIMEN TYPE AND LOCATION INDICATED ON THE CONTAINER LABEL: Right composite resection

Specimen consists of right angle of the mandible with adjacent right lateral tongue and soft tissue. Mandibular bone measures 14 x 1.5 x 0.5 cm and weighs 95.8 g. Attached tongue and soft tissue measure 8.5 x 3.5 x 5.0 cm. There appears to be an ulcer in between the gingiva and lateral tongue that measures 2.8 x 1.5 x 0.6 cm. Adjacent to the ulcer there is a white, firm gritty tumor mass measuring 6.5 AP x 2.4 ML x 3.5 SI cm. The tumor grossly involves the posterior margin and lies 1.5 cm from the anterior margin. The tumor lies 0.3 cm from the deep margin and 0.2 from the medial soft tissue margin.

Specimen is oriented by surgical stitches at anterior and medial portion. The tumor does not appear to be invading bone, grossly.

Posterior soft tissue margin is inked green, medial margin is inked black, anterior margin is inked blue, lateral mucosal margin is inked yellow, and deep/inferior is inked orange. Cassette summary is below:

- H1 Mandible in decal
- H2 Shaved gingival margin lateral
- H3 Anterior perpendicular margin
- H4 Posterior perpendicular margin
- H5 Lateral tongue perpendicular margin
- H6 Deep perpendicular margin
- H7 Tumor and ulcer representative sections
- H8 Representative tumor

Specimen - I

The specimen is received fresh. Both the original label and the [REDACTED] label indicate the patient's name is [REDACTED] and both labels have the same hospital number.

[page 5 of 10]
SPECIMEN TYPE AND LOCATION INDICATED ON THE CONTAINER LABEL: Right neck level 3, 4, 5

The specimen consists of a portion of unoriented yellow fibrofatty tissue that measures 7.0 x 5.5 x 2.4 cm and weighs 37.1 g. There are multiple enlarged white lymph nodes measuring 3.0 cm in greatest dimension (first lymph node), 2.4 cm in greatest dimension (second lymph node), and 1.0 cm in greatest dimension (third lymph node). Representative sections are submitted as indicated in cassette summary.

Cassette summary:

I1: Representative section of first lymph node with third lymph node

I2: Representative section of second lymph node

Specimen - J

The specimen is received fresh. Both the original label and the label indicate the patient's name is [REDACTED] and both labels have the same hospital number.

SPECIMEN TYPE AND LOCATION INDICATED ON THE CONTAINER LABEL: Left level 1

The specimen consists of a portion of unoriented yellow fibrofatty tissue that measures 4.5 x 2.5 x 1.5 cm and weighs 14.2 g. Representative sections are submitted as indicated in cassette summary.

Cassette summary:

J1: Representative sections of salivary gland

Specimen - K

The specimen is received fresh. Both the original label and the label indicate the patient's name is [REDACTED] and both labels have the same hospital number.

SPECIMEN TYPE AND LOCATION INDICATED ON THE CONTAINER LABEL: Left facial node

The specimen consists of a portion of unoriented yellow fibrofatty tissue that measures 1.6 x 1.0 x 0.3 cm. Representative sections are submitted as indicated in cassette summary.

Cassette summary:

K1: One possible lymph node bisected

Specimen - L

The specimen is received fresh. Both the original label and the label indicate the

[page 6 of 10]
patient's name is [REDACTED] and both labels have the same hospital number.

SPECIMEN TYPE AND LOCATION INDICATED ON THE CONTAINER LABEL: Right posterior oral mucosa

The specimen consists of a portion of unoriented yellow fibrofatty tissue that measures 1.2 x 1.0 x 0.4 cm. Representative sections are submitted as indicated in cassette summary.

Cassette summary:

L1: One possible lymph node bisected

Intaoperative Consultation

Patient Information

Patient Name Sex DOB SSN

[REDACTED] Male [REDACTED] xxx-xx-xxxx

Consults signed by

at

Author:

Service: Pathology-Consult Author Type: Physician

Filed:

Note Time:

PATHOLOGY: INTRA-OPERATIVE CONSULTATION

Patient ID:

Name: [REDACTED] **Admission Date:**

Sex: male

MRN: [REDACTED] **Attending Provider:**

Room/Bed:

DOB: [REDACTED]

Specimen/Indications: Buccal margins floor of mouth cancer

Report:

A. Oropharynx, buccal margin, excision (A1FS):

- No evidence of carcinoma.

B. Oropharynx, lingual margin #1, excision (B1FS):

- No evidence of carcinoma.

[page 7 of 10]
C. Oropharynx, lingual margin #2, excision (C1FS):

- No evidence of carcinoma.

D. Oropharynx, deep tongue margin, excision (D1FS):

- No evidence of carcinoma.

Electronically signed by:

Final Diagnosis

A. Buccal margin,FSA1 excision:

- No carcinoma identified.
- Benign, uninvolved salivary gland.
- Acute inflammation present in submucosa.

B. Lingual margin #1,FSB1 excision:

- No carcinoma identified.
- Benign, uninvolved salivary gland.

C. Lingual margin #2,FSC1 excision:

- No carcinoma identified.
- Benign, uninvolved salivary gland.

D. Deep tissue margin,FSD1 excision:

- No carcinoma identified.

E. Level 1A neck contents, excision:

- One benign lymph node (0/1).

F. Right level 2B, excision:

- One lymph node with invasive squamous cell carcinoma (1/1).
- Salivary gland with chronic inflammation.

G. Right facial node, excision:

- One lymph node with invasive squamous cell carcinoma (1/1).

H. Right composite, resection:

- Invasive squamous cell carcinoma.
- Posterior soft tissue margin positive for invasive squamous cell carcinoma.
- See staging summary

I.Right neck , level 3, 4 and 5 , lymph node dissection:

[page 8 of 10]
-Two large matted lymph nodes positive for metastatic squamous cell carcinoma (2/2)

J.Left neck, level 1, lymph node dissection:

-Benign salivary gland.

-No lymph nodes identified.

K.Lymph node, left facial ,excision:

-One lymph node negative for metastatic carcinoma (0/1)

L.Right posterior oral mucosa,excision:

-Benign squamous mucosa.

Comment; status of the bony mandibular margin will be reported in addendum report

STAGING SUMMARY

Clinical

Neoadjuvant Therapy: Indeterminate

Specimen

Specimen: Other (specify): Lateral tongue

Received: Fresh

Procedure: Neck (lymph node) dissection (specify): Right neck level 2,3,4,5

Left neck level 1

Other (specify): Mandible angle resection

Specimen Integrity: Intact

Specimen Size

Dimensions: 14 x 6.5 x 3.5 cm

Specimen Laterality: Right

Tumor Site: Other (specify): Lateral tongue

Tumor Laterality: Right

Tumor Focality: Single focus

Tumor Size

Dimensions: 6.5 x 3.5 x 2.4 cm

Tumor Description: Endophytic;

Ulcerated

Tumor

Histologic Grade: G2: Moderately differentiated

Margins

Invasive: Margin(s) involved by invasive carcinoma

Specify Margin(s), Per Orientation: Posterior soft tissue margin

[page 9 of 10]
In Situ: Margins uninvolved by carcinoma in situ

Accessory Findings

Treatment Effect: Not identified

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Present

Lymph Nodes

Number Examined: 6

Number Involved: 4

Size Greatest Dimension of the Largest Positive Lymph Node (cm): 3

Lymph Nodes, Extranodal Extension: Present

Stage (pTNM): pT3

Pathologic Staging

pT and pN:pN2b

Regional Lymph Nodes (pN): Oropharynx:

Authorizing Provider Information

Name:

Fax:

Phone:

Pager:

PDF Results and Scans

[page 10 of 10]
Lab Information

Lab

Lab Director

Criteria	hw 1/7/14	Yes	No

Source: NCI Genomic Data Commons file b45c0a9e-fce2-4bca-bcbf-01384b8c77f3 (TCGA-QK-AA3K.C9697CE0-2C1D-4629-B4C3-01DD7CA1D91C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).